Somatic mutation profile of tumor specimen TCGA-JW-A852-01A (aliquot TCGA-JW-A852-01A-11D-A351-09) from TCGA case TCGA-JW-A852, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 42.9 years (15,682 days).
Specimen TCGA-JW-A852-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6f4ced3-d3c2-4fb9-95a5-b15619d437e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A852-10A (Blood Derived Normal), aliquot TCGA-JW-A852-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d45f694c-f589-4ca0-964c-1c8437038104

The open-access MAF lists 102 somatic variants for this specimen: 72 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 29, Nonsense Mutation 6, Intron 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 148/264 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs121913301, CM951105, CM961226, COSV57296833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2957C>T p.A986V (on ENST00000404938 / NM_001163941.2; = p.A541V on NM_178559.6) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs201974989; called by muse, mutect2, varscan2
- ADGRL3 | c.1091G>A p.R364Q (on ENST00000506720 / NM_001322402.2; = p.R296Q on NM_015236.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390649818, COSV72266053; called by muse, mutect2, varscan2
- AP1M1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.135); catalogued as rs988117238, COSV52224972; called by muse, mutect2, varscan2
- BARHL2 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as COSV64980814; called by muse, mutect2, varscan2
- CDHR2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56134893, COSV56143179; called by muse, mutect2, varscan2
- CECR2 | c.1653G>A p.W551* (on ENST00000342247 / NM_001290047.2; = p.W368* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV52836607; called by muse, mutect2, varscan2
- CLTC | c.1396C>G p.L466V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as COSV52245105; called by muse, mutect2, varscan2
- COL6A2 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.203); catalogued as rs373611722; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- DNMT1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV61576696; called by muse, mutect2, varscan2
- DPP10 | c.311T>A p.I104N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV59666286; called by muse, mutect2, varscan2
- DPYSL2 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs774132967, COSV60782084, COSV60784505; called by muse, mutect2, varscan2
- EEF1A1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.453); catalogued as rs267601114, COSV100303481, COSV58548965; called by muse, mutect2, varscan2
- EHD1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57733679; called by muse, mutect2, varscan2
- ENPEP | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV54447299; called by muse, mutect2
- FANCD2 | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs754740540, COSV55033262; called by muse, mutect2, varscan2
- FBXO31 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61147739, COSV61148767; called by muse, mutect2, varscan2
- FOXK2 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs773115793, COSV58877066; called by muse, mutect2, varscan2
- GART | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV67818056; called by muse, mutect2, varscan2
- HELZ | c.3033G>C p.K1011N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV62376490; called by muse, mutect2, varscan2
- HEXD | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.376); catalogued as COSV60062911; called by muse, varscan2
- JCAD | c.2630A>G p.E877G | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV64758113; called by muse, mutect2
- LAMA4 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV54568710; called by muse, mutect2, varscan2
- LARP1 | c.1807G>C p.E603Q (on ENST00000518297 / NM_033551.3; = p.E526Q on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60424936; called by muse, mutect2, varscan2
- MGA | c.8211G>C p.Q2737H (on ENST00000219905 / NM_001164273.1; = p.Q2528H on NM_001080541.2) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV54949380; called by muse, mutect2, varscan2
- MGRN1 | c.137C>A p.T46N | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52148537; called by muse, mutect2, varscan2
- MRM3 | c.1038G>T p.W346C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58679293; called by muse, mutect2, varscan2
- MUC16 | c.36076C>A p.H12026N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.708); catalogued as COSV67447055; called by muse, mutect2, varscan2
- NETO1 | c.607A>G p.K203E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV55002093; called by muse, mutect2, varscan2
- PCDHA1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65372783; called by muse, mutect2, varscan2
- PCDHGA2 | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.308); catalogued as rs1483184484, COSV53903802; called by muse, mutect2, varscan2
- PFDN4 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 38/120 reads (32%) | catalogued as COSV65062809; called by muse, mutect2, varscan2
- POM121L12 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.261); catalogued as COSV68692284; called by muse, mutect2, varscan2
- PRAMEF6 | c.1373G>T p.C458F | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1165689597; called by muse, mutect2, varscan2
- PRH2 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV67171555; called by muse, mutect2, varscan2
- PSTPIP1 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.988); catalogued as rs1014025734, COSV51198255; called by muse, mutect2, varscan2
- RAPGEF1 | c.2303A>G p.E768G | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV64697937; called by muse, mutect2, varscan2
- RC3H2 | c.3055G>T p.D1019Y | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.99); catalogued as COSV61798618; called by muse, mutect2, varscan2
- RIOK3 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs774183551, COSV59772087; called by muse, mutect2, varscan2
- RNH1 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs142171562; called by muse, mutect2, varscan2
- RNPEP | c.892G>C p.G298R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55238966; called by muse, mutect2, varscan2
- SIGLEC8 | c.416T>A p.L139* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs957419105, COSV58471994; called by muse, mutect2, varscan2
- SKAP1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1273505806, COSV61144312; called by muse, mutect2, varscan2
- SNX27 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV64325670; called by muse, mutect2, varscan2
- SPACA3 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV52190444; called by muse, mutect2, varscan2
- SPOCK3 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as rs1006424613, COSV62717367; called by muse, mutect2, varscan2
- SRPRB | c.243T>A p.F81L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV71749015; called by muse, mutect2, varscan2
- TCN1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV57252163; called by muse, mutect2, varscan2
- TENM1 | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.24); catalogued as COSV64425669; called by muse, mutect2, varscan2
- TRAPPC2L | c.15C>G p.I5M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs748351026, COSV51935815, COSV51936042; called by mutect2, varscan2
- TRPM1 | c.3704C>T p.A1235V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs757962189, COSV56630861; called by muse, mutect2, varscan2
- TTN | c.17557G>A p.V5853I (on ENST00000591111; = p.V4926I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | PolyPhen benign (0.003); catalogued as COSV59902087; called by muse, mutect2, varscan2
- UBE2O | c.1813G>A p.G605S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100084107, COSV60060473; called by muse, mutect2, varscan2
- UGT1A5 | c.571T>C p.S191P | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59382706; called by muse, mutect2, varscan2
- USP32 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1263636360, COSV100341340, COSV56264483; called by muse, mutect2, varscan2
- USP6 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 28/82 reads (34%) | catalogued as rs756052036, COSV51474971; called by muse, mutect2, varscan2
- USP9X | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV61066344; called by muse, mutect2, varscan2
- ZC3H12A | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66103908; called by muse, mutect2, varscan2
- ZFR2 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53596515; called by muse, mutect2, varscan2
- ZNF366 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1388433116, COSV59213921; called by muse, mutect2
- ZNF415 | c.982T>C p.Y328H | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV54699202; called by muse, mutect2
- ZNF638 | c.4850C>G p.A1617G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.197); catalogued as COSV52482331; called by muse, mutect2, varscan2
- ZNF91 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs12976753, COSV56080852; called by muse, mutect2, varscan2
- ZXDB | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66492355; called by muse, mutect2, varscan2
- FLYWCH1 | c.606_624del p.Q203Efs*28 (on ENST00000253928 / NM_001308068.2; = p.Q202Efs*28 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by mutect2, pindel
- IGBP1P2 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- LILRB5 | c.1630-2A>G p.X544_splice (on ENST00000449561 / NM_001081442.3; = p.X543_splice on NM_006840.5) | Splice Site (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- OR8K3 | c.898_899insA p.L300Hfs*7 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- ABCA13 | c.13335C>T p.N4445= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs746139643, COSV101291209; called by muse, mutect2, varscan2
- AMY2B | c.402C>T p.F134= | Silent (SNP) | VAF 80/341 reads (23%) | catalogued as COSV63714126; called by muse, mutect2, varscan2
- BTBD11 | c.2625G>A p.A875= (on ENST00000280758 / NM_001018072.2; = p.A412= on NM_001017523.2) | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs769586165, COSV55017683, COSV55028786; called by muse, mutect2, varscan2
- CCDC178 | c.1308A>G p.A436= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV55760575; called by muse, mutect2, varscan2
- CCDC88B | c.489C>T p.L163= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV57264994; called by muse, mutect2, varscan2
- COLEC11 | c.786C>T p.F262= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV52591630; called by muse, mutect2, varscan2
- CSMD1 | c.6549C>T p.H2183= (on ENST00000520002; = p.H2182= on NM_033225.6) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs776073303, COSV59394928; called by muse, mutect2, varscan2
- CTNND1 | c.2355T>C p.V785= (on ENST00000399050 / NM_001085458.2; = p.V779= on NM_001331.3) | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV62382277; called by muse, mutect2, varscan2
- EHMT1 | c.2172C>T p.L724= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV58371242; called by muse, mutect2, varscan2
- FOXRED2 | c.1860G>C p.L620= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV53398960; called by muse, mutect2, varscan2
- FSTL5 | c.1728G>A p.L576= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV60182764; called by muse, mutect2, varscan2
- KMT2A | c.1026A>G p.K342= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV63282379; called by muse, mutect2, varscan2
- KMT2A | c.10317C>T p.A3439= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs1020726478, COSV63282382; called by muse, mutect2, varscan2
- L1CAM | c.2373C>A p.V791= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV62826971; called by muse, mutect2, varscan2
- LAMA2 | c.6186C>G p.L2062= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs975864468, COSV70339427, COSV70348736; called by muse, mutect2, varscan2
- MACF1 | c.19392C>T p.I6464= (on ENST00000372915; = p.I4509= on NM_012090.5) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs747884788, COSV99241927; called by muse, mutect2, varscan2
- MUC2 | c.4038C>G p.L1346= | Silent (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- MYO18B | c.7155G>A p.R2385= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV59144239; called by mutect2, varscan2
- OR10W1 | c.594T>C p.I198= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV67720214; called by muse, mutect2
- PABPC5 | c.936A>T p.T312= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV100442161; called by muse, mutect2
- PCDH7 | c.2799G>A p.K933= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- PCDHGB7 | c.21G>A p.Q7= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV53903814; called by muse, mutect2, varscan2
- PTCD1 | c.339G>A p.R113= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV52856503; called by muse, mutect2, varscan2
- SNX27 | c.321G>C p.V107= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as COSV64325662; called by muse, mutect2, varscan2
- TICRR | c.3231C>A p.I1077= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV51538244; called by muse, mutect2, varscan2
- VPS16 | c.1725C>T p.F575= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as COSV66792315; called by muse, mutect2, varscan2
- ZAP70 | c.1095C>T p.D365= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV53852599, COSV99385352; called by muse, mutect2, varscan2
- ZDHHC11 | c.1014G>A p.S338= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs267600724, COSV52063025, COSV99363447; called by muse, mutect2, varscan2
- ZNF19 | c.1347C>A p.L449= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV55506970, COSV99867104; called by muse, mutect2, varscan2
- NRP1 | c.981+4512C>T | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as rs746172345; called by muse, mutect2, varscan2
